Surgical pathology report (de-identified scan), TCGA case TCGA-08-0348, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0348-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0348-01A

FINAL PATHOLOGIC DIAGNOSIS

- A. Right occiput, biopsy: WHO-II Glioblastoma multiforme, Grade 4; see comment.
- B. Right occiput, craniotomy: Necrotic tissue, see comment.

COMMENT: Microscopic sections from specimen A show a highly cellular astrocytic neoplasm with marked nuclear pleomorphism, endothelial proliferation, foci of necrosis and scattered mitotic figures. The infiltrative edge is well demonstrated on slide A1.

By [REDACTED] and previous [REDACTED] criteria, this is a glioblastoma multi forme. By [REDACTED] criteria, it is a Grade 4 astrocytoma. An immunoperoxidase stain for Mib-1 will be performed on A2 and the results reported by addendum.

In specimen B, section B1 shows necrotic tissue, including necrotic blood vessels with no viable neoplasm.

Intraoperative Diagnosis

FS1 (A) Brain, biopsy: WHO-II Glioblastoma multiforme, grade 4, tissue section and cytologic prep. (Dr. [REDACTED])

Gross Description

Part A. The specimen is received fresh for frozen section analysis labeled with the patient's name, number, and "tumor (brain)," and consists of two fragments of soft white-tan tissue measuring 1.0 cm in greatest dimension in aggregate. A representative section is submitted for frozen section analysis and subsequently in cassette A1. The remainder of the unfrozen tissue is submitted in cassette A2.

Part B. The specimen is received in formalin labeled with the patient's name, number, and "tumor (brain)," and consists of one fragmented piece of soft white-tan tissue measuring 1.0 cm in greatest dimension. The entire specimen is submitted in cassette B1.

Clinical History

[page 2 of 2]
The patient is a [REDACTED] with brain tumor undergoes biopsy.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]/Pathology Resident

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b99a0e52-6aa3-4b3b-8a26-02ddd805de9b (TCGA-08-0348.EC152A12-B887-4AB8-A937-D7C00E953F51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).